Somatic mutation profile of tumor specimen TARGET-40-NAASJI-01A (aliquot TARGET-40-NAASJI-01A-01D) from TARGET case TARGET-40-NAASJI, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Age at diagnosis: 19.4 years (7,074 days).
Specimen TARGET-40-NAASJI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8f4914f-73a5-49cf-961b-12426776c4b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAASJI-10A (Blood Derived Normal), aliquot TARGET-40-NAASJI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4395ef6-e037-4b13-997e-9cab0a47327a

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, Intron 2, 3'UTR 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375+2T>A p.X125_splice | Splice Site (SNP) | VAF 13/28 reads (46%) | hotspot (GDC flag); catalogued as rs1555526469, CS147127, COSV52663814, COSV52664353, COSV52730362; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.4337A>G p.K1446R (on ENST00000272895 / NM_173076.3; = p.K1128R on NM_015657.3) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1254400144; called by muse, mutect2, varscan2
- AC099489.1 | c.3445C>T p.R1149W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as rs747887851, COSV100763324; called by muse, mutect2, varscan2
- AGO1 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV100940868; called by muse, varscan2
- CLTCL1 | c.3211G>A p.V1071I | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369214595; called by muse, mutect2, varscan2
- FAM102A | c.983C>T p.A328V (on ENST00000373095 / NM_001035254.3; = p.A186V on NM_203305.2) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs1287066912; called by muse, varscan2
- HEPHL1 | c.2240C>T p.A747V | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as COSV59894802, COSV59896726; called by muse, mutect2
- NT5C1B | c.850G>A p.A284T (on ENST00000359846 / NM_001199086.2; = p.A224T on NM_033253.4) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); catalogued as rs865861415; called by muse, varscan2
- OR12D2 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs775339584, COSV65830527; called by muse, mutect2, varscan2
- SLC5A7 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV50890816, COSV50903566; called by muse, varscan2
- WARS2 | c.887G>A p.G296D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV99346747; called by muse, varscan2
- GBA | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, varscan2
- LGALS3BP | c.1698C>A p.F566L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- NUCB1 | c.1029dup p.E344Rfs*8 | Frame Shift Ins (INS) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- PCDH17 | c.1505G>A p.G502D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC12A2 | c.842G>C p.G281A | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TBC1D8B | c.3118G>A p.A1040T | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.026); called by muse, varscan2
- TREH | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); called by muse, varscan2
- YIPF2 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- BRAF | c.177A>G p.E59= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- KIRREL2 | c.102G>T p.V34= | Silent (SNP) | VAF 53/81 reads (65%) | catalogued as rs763396476; called by muse, mutect2, varscan2
- TCF12 | c.384C>A p.G128= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, varscan2
- ZNF200 | c.321T>C p.Y107= | Silent (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- COL11A2 | c.*752G>A | 3'UTR (SNP) | VAF 4/28 reads (14%) | called by muse, varscan2
- EPB41L4A | c.*65T>C | 3'UTR (SNP) | VAF 3/22 reads (14%) | called by muse, varscan2
- SLC46A2 | c.1371-10A>G | Intron (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- TTC21A | c.3697-20C>G | Intron (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
